Surgical pathology report (de-identified scan), TCGA case TCGA-19-5951, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5951-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

TCGA-19-5951

A. AND D. LEFT PARIETAL LESION, B. DEEP INFERIOR MARGIN AND C. SUPERIOR LATERAL MARGIN, BIOPSY AND EXCISION:

--GLIOBLASTOMA MULTIFORME (WHO GRADE IV), SEE NOTE.

Note: There is microvascular proliferation. No definite tumor necrosis is identified.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A, B: Microscopic and touch imprint: Malignant astrocytoma

C: Microscopic: Minimal hypercellularity consistent with glioma margin.

Clinical History:

Left parietal lesion

Specimens Submitted As:

A:BIOPSY LEFT PARIETAL LESION

B:DEEP INFERIOR MARGIN

C:SUPERIOR LATERAL MARGIN

D:LEFT PARIETAL LESION

Gross Description:

A: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "biopsy left parietal lesion", are multiple pink-white soft tissue fragments, 0.8 x 0.4 x 0.3 cm in aggregate. Representative tissue is submitted for touch imprint and frozen section. The remainder of the specimen is submitted entirely for permanent.

B: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "deep inferior margin", are multiple pink-white soft tissue fragments, 0.6 x 0.4 x 0.3 cm in aggregate. The specimen is submitted entirely for touch imprint and frozen section.

C. Received fresh for intraoperative consultation, labeled with the patient's name and hospital number, are multiple irregular fragments of tan-pink soft tissue measuring approximately 1 x 0.6 x 0.2 cm in aggregate. A frozen section is performed on the specimen, and the entire specimen is submitted in one cassette.

D: Received fresh, labeled with the patient's name and number, are multiple tan-gray to focally pink-tan irregular soft tissue fragments measuring 5.0 x 4.2 x 0.8 cm in aggregate. A portion is submitted to touch imprint. Submitted entirely in six cassettes.

Summary cassettes

[page 2 of 2]
Specimen	Label	Site
A	1	remaining frozen tissue
	2	permanent, entirely submitted
B	1-2	remaining frozen tissue
C	1	frozen section of entire specimen

Source: NCI Genomic Data Commons file 5580df99-3002-4da6-a45e-9b0ae54556f6 (TCGA-19-5951.B43D622B-0FA9-4114-92AD-BDBD2033CCB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).